Gene-level copy-number profile of tumor specimen TCGA-78-7161-01A from TCGA case TCGA-78-7161, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.3 years (25,294 days).
Specimen TCGA-78-7161-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.132fea26-dd36-4dc1-9fab-69c4e23336ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7161-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/030ff47b-9e21-4dd7-8bf1-953cd34d6fce

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 461; copy number 2: 10,665; copy number 3: 24,880; copy number 4: 17,720; copy number 5: 3,174; copy number 6: 1,970; copy number 7: 329; copy number 8: 296; copy number 9: 182; copy number 10: 65; copy number 11: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7161-01A-11D-2035-01): tumor purity 0.75, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 939 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,383,838–42,703,805, 127 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:158,398,522–159,055,155, 29 genes, copy number 9: OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P, PYHIN1, IFI16.
- chr1:199,016,133–201,469,237, 47 genes, copy number 8 (within-gene range 4–8): LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3, PHLDA3, AC096677.2.
- chr1:202,878,282–205,357,090, 83 genes, copy number 8 (broad region; genes not listed).
- chr6:67,210,408–67,625,464, 5 genes, copy number 8: AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA.
- chr6:88,047,056–88,963,618, 10 genes, copy number 7 (within-gene range 2–7): AL136096.1, SPACA1, CNR1, AL121835.2, AL139042.1, AL121835.1, ACTBP8, AL139090.1, RNGTT, SNORA73.
- chr8:112,148,742–121,119,754, 73 genes, copy number 7 (broad region; genes not listed).
- chr8:130,780,301–133,947,335, 42 genes, copy number 7: ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3.
- chr11:74,311,362–76,144,232, 71 genes, copy number 8 (broad region; genes not listed).
- chr11:77,322,017–81,040,236, 54 genes, copy number 7 (within-gene range 4–7): PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2.
- chr11:94,545,330–94,740,355, 1 gene, copy number 7 (within-gene range 4–7): AP000943.2.
- chr11:94,638,038–95,234,391, 19 genes, copy number 7 (within-gene range 4–7): AP000943.1, LINC02700, AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1.
- chr12:66,767–2,697,950, 53 genes, copy number 9 (within-gene range 5–9): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3.
- chr12:5,226,196–5,383,653, 3 genes, copy number 7 (within-gene range 4–7): LINC02443, AC006206.2, AC006206.1.
- chr14:28,673,241–32,159,728, 67 genes, copy number 11 (broad region; genes not listed).
- chr14:35,447,003–37,596,059, 46 genes, copy number 10: AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.
- chr16:35,134,514–35,645,180, 45 genes, copy number 8–10: VN1R69P, AC023824.5, AC023824.6, UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1.
- chr16:71,833,787–74,613,221, 64 genes, copy number 8 (broad region; genes not listed).
- chr18:47,390–4,459,458, 100 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 461. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
